TCGA case TCGA-AR-A0TZ — Breast Invasive Carcinoma (TCGA-BRCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast; Tissue source site: Mayo. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c7c34fd9-3021-45b7-b6ff-30b4196585a8

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 43 years; Vital status: Dead; Days to death: 3,262 days (8.9 years).

Diagnoses (3)
1. Infiltrating duct carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8500/3; ICD-10 code: C50.9; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 43.0 years (15,720 days); Year of diagnosis: 2004; Method of diagnosis: Core Biopsy; AJCC pathologic T: T2; AJCC pathologic N: N2; AJCC pathologic M: M1; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Bone, NOS / Breast, Left Upper Outer.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 6; Lymph nodes tested: 30.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide; Treatment intent type: Adjuvant.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Doxorubicin; Treatment intent type: Adjuvant.
   Treatment given: Treatment type: Hormone Therapy; Treatment intent type: Adjuvant.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Course number: 1.
   Treatment given: Treatment type: Surgery, NOS; Treatment intent type: First-Line Therapy; Initial disease status: Initial Diagnosis; Margin status: Uninvolved; Treatment anatomic sites: Breast.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Tamoxifen; Treatment intent type: Adjuvant.
2. Diagnosis record without a diagnosis name: Age at diagnosis: 46.6 years (17,033 days); Days to diagnosis: 1,313 days (3.6 years); Prior treatment: Yes.
3. Metastasis of diagnosis 1 (Infiltrating duct carcinoma, NOS), site: Bone, NOS. Age at diagnosis: 46.6 years (17,033 days); Days to diagnosis: 1,313 days (3.6 years); Prior treatment: Yes.

Follow-up (2 entries)
- Day 1,313 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Bone, NOS; Days to progression: 1,313 days (3.6 years).
- Follow-up contacts recording only the day: day 2,316, day 3,262.

Molecular and laboratory tests
- ERBB2 (IHC): Equivocal; Staining intensity value: 2+.
- ERBB2 amplification (FISH): Negative.
- ESR1 (IHC): Positive.
- PGR (IHC): Positive.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Menopause status: Premenopausal.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AR-A0TZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 290 mg.
  Slide TCGA-AR-A0TZ-01A-01-BSA: Section location: Bottom; Percent tumor cells: 60; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 40; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-AR-A0TZ-01A-01-TSA: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 40; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-AR-A0TZ-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-AR-A0TZ-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Surgical procedure first: Modified Radical Mastectomy; Histologic diagnosis: Infiltrating Ductal Carcinoma; Menopause status: Pre (<6 months since LMP AND no prior bilateral ovariectomy AND not on estrogen replacement); Her2 IHC score: 2+; Method initial path diagnosis: Core needle biopsy; Prospective collection: No; Retrospective collection: Yes; New tumor event er status IHC positive: 70-79%; New tumor event pr status IHC positive: <10%; New tumor event her2 positivity IHC score: 1+.
- Anatomic neoplasm subdivisions: Anatomic organ subdivision: Left Upper Outer Quadrant.
- First nonlymph node metastasis anatomic sites: Metastasis site: Bone.
- Follow-up form 1: New tumor event type: Distant Metastasis; New tumor event site: Bone.
- Follow-up form 2: Lost to follow-up: No.
- Drug treatment 1: Regimen number: 1.
- Drug treatment 5: Regimen number: 1; Pharmaceutical therapy drug name: Cytoxan.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 3,262 days; disease-specific survival: event status not recorded, 3,262 days; disease-free interval: event (new tumor event after initially disease-free), 1,313 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,313 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-AR-A0TZ-01A-12D-A087-01): tumor purity 0.86, ploidy 1.76, whole-genome doublings 0.
